Somatic mutation profile of tumor specimen TCGA-04-1336-01A (aliquot TCGA-04-1336-01A-01W-0488-09) from TCGA case TCGA-04-1336, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 55.5 years (20,271 days).
Specimen TCGA-04-1336-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24dd2610-0d9f-4fb8-9ecd-f0352d886845.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1336-11A (Solid Tissue Normal), aliquot TCGA-04-1336-11A-01W-0487-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a52c8205-eb4e-4d12-a754-629609c59056

The open-access MAF lists 74 somatic variants for this specimen: 58 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 15, Frame Shift Del 6, Nonsense Mutation 5, Splice Site 2, In Frame Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 38/80 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV52517787, COSV52518375; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 41/51 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as COSV51844910; called by muse, mutect2, varscan2
- ADAMTSL1 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52818040; called by muse, mutect2, varscan2
- ADGRG4 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 269/343 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs746435155, COSV54959465; called by muse, mutect2, varscan2
- AHNAK2 | c.10065C>A p.D3355E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.198); catalogued as COSV100315542, COSV60914561; called by muse, mutect2, varscan2
- ALOX15B | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66479630; called by muse, mutect2, varscan2
- ALPK1 | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 101/122 reads (83%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV51586712; called by muse, mutect2, varscan2
- AP000311.1 | c.190A>G p.R64G | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated, low confidence (0.22); catalogued as COSV51708666; called by muse, mutect2, varscan2
- C11orf53 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99724648; called by muse, mutect2, varscan2
- CABS1 | c.1062G>C p.K354N | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV56733886; called by muse, mutect2, varscan2
- CDH17 | c.1456A>G p.K486E | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.137); catalogued as COSV50331190; called by muse, mutect2, varscan2
- CPXM1 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV66045874; called by muse, mutect2, varscan2
- CUBN | c.5732G>C p.R1911T | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV64718991; called by muse, mutect2, varscan2
- DENND2A | c.2284C>A p.L762M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52053266, COSV99327124; called by muse, mutect2, varscan2
- DPYS | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.385); catalogued as rs745993895, COSV60910032; called by muse, mutect2, varscan2
- DSC2 | c.808A>T p.K270* | Nonsense Mutation (SNP) | VAF 61/149 reads (41%) | catalogued as COSV51866202; called by muse, mutect2, varscan2
- EPHB1 | c.675C>A p.C225* | Nonsense Mutation (SNP) | VAF 28/720 reads (4%) | catalogued as COSV101212761, COSV67669891; called by muse, mutect2
- ERG | c.986C>T p.S329L (on ENST00000398919 / NM_001243428.1; = p.S305L on NM_004449.4) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55734295; called by muse, mutect2, varscan2
- ETAA1 | c.1864C>G p.Q622E | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV55473725; called by muse, mutect2, varscan2
- FCGBP | c.12385G>A p.V4129M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs749313850; called by muse, mutect2, varscan2
- GABPB1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 130/151 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV99589609; called by muse, mutect2, varscan2
- IQCC | c.112C>G p.R38G | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs560946593, COSV52209549; called by muse, mutect2, varscan2
- ITGA11 | c.3285A>C p.A1095= | Splice Region (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100241040; called by muse, mutect2
- KIFC2 | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs1251167801, COSV56761632; called by muse, mutect2
- KRT6A | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV58105903; called by muse, mutect2, varscan2
- KRTAP13-3 | c.259A>C p.M87L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61879529; called by muse, mutect2, varscan2
- LAMB1 | c.3109C>A p.Q1037K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV55966451; called by muse, mutect2, varscan2
- LAMC1 | c.2505T>A p.D835E | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51148648; called by muse, mutect2, varscan2
- LMBR1L | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 2/20 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99918620; called by muse, mutect2
- LNX2 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as COSV60336462; called by muse, mutect2, varscan2
- MAMSTR | c.1199C>T p.S400F (on ENST00000318083 / NM_001130915.2; = p.S297F on NM_182574.2) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.879); catalogued as COSV58881949; called by muse, mutect2, varscan2
- MLIP | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 231/537 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs778702684, COSV51431828; called by muse, mutect2, varscan2
- MTNR1A | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV56156655; called by muse, mutect2, varscan2
- MYT1 | c.3310G>C p.E1104Q | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV60508008; called by muse, mutect2
- PAK2 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 323/881 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV59082205; called by muse, mutect2, varscan2
- PCDHB9 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as rs1554282848, COSV53375004; called by muse, mutect2, varscan2
- PLD5 | c.848G>T p.W283L (on ENST00000442594; = p.W221L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV59151551; called by muse, mutect2, varscan2
- PRAMEF12 | c.991C>A p.L331M | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); catalogued as rs960570403, COSV63215722; called by muse, mutect2, varscan2
- PSKH2 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV52611026; called by muse, mutect2, varscan2
- PXK | c.202-1G>T p.X68_splice | Splice Site (SNP) | VAF 46/62 reads (74%) | catalogued as COSV57088001, COSV57089086; called by muse, mutect2, varscan2
- SMG8 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as COSV56285946; called by muse, mutect2, varscan2
- SYNGAP1 | c.2377A>T p.K793* | Nonsense Mutation (SNP) | VAF 53/121 reads (44%) | catalogued as rs1554122165, COSV53382704; called by muse, mutect2, varscan2
- TMEM164 | c.833C>T p.A278V (on ENST00000372068 / NM_032227.4; = p.A129V on NM_017698.2) | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV55811640; called by muse, mutect2
- TNRC6A | c.3065G>T p.W1022L | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100169533; called by muse, mutect2, varscan2
- TNRC6A | c.3066G>T p.W1022C | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59369171, COSV59369272; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1961T>A p.V654D | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV51956904; called by muse, mutect2, varscan2
- ZFHX3 | c.10294T>A p.S3432T | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV51723082; called by muse, varscan2
- ZFHX4 | c.4584T>A p.N1528K | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV51447303; called by muse, mutect2, varscan2
- ARHGAP20 | c.1363_1375del p.V455Ifs*9 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | called by mutect2, pindel, varscan2
- ASTN1 | c.2229_2244del p.Q743Hfs*11 | Frame Shift Del (DEL) | VAF 93/244 reads (38%) | called by mutect2, pindel, varscan2
- CEACAM1 | c.959-18_959del p.X320_splice | Splice Site (DEL) | VAF 30/112 reads (27%) | called by mutect2, pindel, varscan2
- CETN1 | c.334_363delinsAT p.L112Ifs*6 | Frame Shift Del (DEL) | VAF 25/67 reads (37%) | called by pindel, varscan2*
- CSMD1 | c.7907_7911del p.G2636Vfs*56 (on ENST00000520002; = p.G2635Vfs*56 on NM_033225.6) | Frame Shift Del (DEL) | VAF 73/218 reads (33%) | called by pindel, varscan2
- MRC1 | c.1964G>C p.R655T | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SFPQ | c.1592_1600del p.Q531_N533del | In Frame Del (DEL) | VAF 33/78 reads (42%) | called by mutect2, pindel, varscan2
- SHROOM3 | c.1858_1867del p.S620Qfs*25 | Frame Shift Del (DEL) | VAF 38/99 reads (38%) | called by mutect2, pindel, varscan2
- SLC1A2 | c.1111_1117del p.T371Vfs*13 | Frame Shift Del (DEL) | VAF 102/277 reads (37%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.1821T>C p.T607= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV67133752; called by muse, mutect2, varscan2
- AHNAK2 | c.8379G>A p.A2793= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs371203043; called by muse, mutect2
- ATP10B | c.2133C>T p.A711= | Silent (SNP) | VAF 36/44 reads (82%) | catalogued as COSV59155711; called by muse, mutect2, varscan2
- CELA2A | c.585C>T p.S195= | Silent (SNP) | VAF 85/166 reads (51%) | catalogued as rs1002666141, COSV62747706; called by muse, mutect2, varscan2
- DLG5 | c.4015A>C p.R1339= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV64948515; called by muse, mutect2, varscan2
- ELN | c.1617G>A p.Q539= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as COSV52711668; called by muse, mutect2, varscan2
- FLI1 | c.849G>A p.L283= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1179005819, COSV55645541; called by muse, mutect2, varscan2
- GABPB1 | c.183T>A p.G61= | Silent (SNP) | VAF 132/153 reads (86%) | catalogued as COSV99589606; called by muse, mutect2, varscan2
- HERC5 | c.1848T>C p.T616= | Silent (SNP) | VAF 55/60 reads (92%) | catalogued as COSV52041164; called by muse, mutect2, varscan2
- ILRUN | c.588G>T p.T196= (on ENST00000374023 / NM_024294.4; = p.T130= on NM_022758.6) | Silent (SNP) | VAF 65/131 reads (50%) | catalogued as COSV64990463; called by muse, mutect2, varscan2
- MAGI2 | c.1881G>C p.R627= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs989791806, COSV62671707; called by muse, mutect2, varscan2
- MYO19 | c.156G>T p.L52= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- NOP2 | c.450T>G p.S150= (on ENST00000322166 / NM_001258308.2; = p.S146= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/33 reads (82%) | catalogued as COSV58904001; called by muse, mutect2, varscan2
- POU3F4 | c.1032G>A p.P344= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs41312552, COSV100937251, COSV64539573; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1335G>C p.G445= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV53453620; called by muse, mutect2, varscan2
- UBTFL2 | n.158A>T | RNA (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
